Somatic mutation profile of tumor specimen TCGA-HU-A4GQ-01A (aliquot TCGA-HU-A4GQ-01A-11D-A25D-08) from TCGA case TCGA-HU-A4GQ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 71.7 years (26,200 days).
Specimen TCGA-HU-A4GQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 771a1a15-39b0-47a8-821e-8dbfd0e80911.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4GQ-10A (Blood Derived Normal), aliquot TCGA-HU-A4GQ-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/130a54ce-e31d-456e-8681-5edb347f9761

The open-access MAF lists 2,184 somatic variants for this specimen: 1,666 protein-altering or splice-affecting, 482 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,123, Silent 482, Frame Shift Del 335, Frame Shift Ins 76, Nonsense Mutation 59, Splice Site 26, In Frame Del 24, Splice Region 18, Intron 17, RNA 8, 3'UTR 4, Translation Start Site 3.

Variants (750 of 2,184; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- CFTR | c.2089del p.R697Gfs*25 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | catalogued as rs397508341, COSV50040644; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL4A4 | c.4760del p.P1587Hfs*16 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | catalogued as rs1206142672, CM1310323; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CPS1 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1553512642, CM114326, CM984625, COSV51805942; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CYP21A2 | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 95/368 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201552310, CM031955, CM920231, CM990464, COSV64475788; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.10133del p.N3378Tfs*24 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs863224975, CD013473; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DMD | c.5697del p.K1899Nfs*2 | Frame Shift Del (DEL) | VAF 31/57 reads (54%) | catalogued as rs794727661, CD050845, CD093452; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- LDLR | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs879254589, CM067689, COSV52942362; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH6 | c.3312del p.F1104Lfs*11 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | catalogued as rs267608092; ClinVar: not provided / pathogenic; called by pindel, varscan2
- NPC1 | c.3289G>A p.D1097N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs758829443, CM054026, COSV99340499; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PAFAH1B1 | c.910del p.S304Vfs*29 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | catalogued as rs587784292; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 31/116 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV55874903, COSV99836298; called by muse, mutect2, varscan2
- PIK3CA | c.3061T>C p.Y1021H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV55901519, COSV55910253; called by muse, mutect2, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 35/117 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TRIP11 | c.1622del p.K541Rfs*17 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | catalogued as rs1420691965; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TTN | c.47086C>T p.R15696* (on ENST00000591111; = p.R8272* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as rs1343120755, COSV100624672, COSV59893970; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A3GALT2 | c.235del p.A79Lfs*27 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | catalogued as rs770563385; called by mutect2, pindel, varscan2
- ABCA2 | c.3824C>T p.P1275L (on ENST00000614293; = p.P1245L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs200421241; called by muse, mutect2, varscan2
- ABCA3 | c.2233G>T p.G745W | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57051474; called by muse, mutect2, varscan2
- ABCA7 | c.5305C>A p.L1769M | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.379); catalogued as COSV54026765; called by muse, mutect2, varscan2
- ABCC1 | c.4304G>A p.R1435H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60682969; called by muse, mutect2, varscan2
- ABCG8 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762452685, COSV55391738; called by muse, mutect2, varscan2
- ABHD2 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748725026, COSV61773037; called by muse, mutect2, varscan2
- ABTB1 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs772031165, COSV51740651; called by muse, mutect2, varscan2
- AC098582.1 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52018813; called by muse, mutect2, varscan2
- AC136428.1 | c.105del p.S36Pfs*2 | Frame Shift Del (DEL) | VAF 33/126 reads (26%) | catalogued as rs763538641; called by mutect2, varscan2
- ACACB | c.769dup p.D257Gfs*29 | Frame Shift Ins (INS) | VAF 14/80 reads (18%) | catalogued as rs768607691; called by mutect2, varscan2
- ACACB | c.4779C>A p.F1593L | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV58131206; called by muse, mutect2, varscan2
- ACAD8 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.16); catalogued as COSV55539676; called by muse, mutect2, varscan2
- ACAD9 | c.1516T>C p.Y506H | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV58306945; called by muse, mutect2, varscan2
- ACADL | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV52052780; called by muse, mutect2, varscan2
- ACAN | c.4745G>A p.G1582E | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs763243954, COSV61358324; called by muse, mutect2
- ACAN | c.6487G>A p.A2163T | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.091); catalogued as rs766547434, COSV61358332; called by muse, mutect2, varscan2
- ACBD4 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV58851270; called by muse, mutect2, varscan2
- ACHE | c.646_648del p.E216del | In Frame Del (DEL) | VAF 29/167 reads (17%) | catalogued as rs761701642; called by mutect2, pindel, varscan2
- ACIN1 | c.3524G>A p.R1175H | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.965); catalogued as rs764973278, COSV52974684, COSV52981343; called by muse, varscan2
- ACIN1 | c.3451del p.R1151Gfs*79 | Frame Shift Del (DEL) | VAF 30/188 reads (16%) | catalogued as COSV52974975; called by pindel, varscan2
- ACKR3 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV56021063; called by muse, mutect2, varscan2
- ACOT8 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs150475004; called by muse, varscan2
- ACOX3 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs755214872, COSV62711432; called by muse, mutect2, varscan2
- ACSF2 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51971852; called by muse, mutect2, varscan2
- ACSS2 | c.1883C>T p.T628I | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV53623824; called by muse, mutect2, varscan2
- ACTL6A | c.269del p.N90Mfs*47 | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | catalogued as rs1560010257; called by mutect2, pindel, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 47/88 reads (53%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM28 | c.224del p.N75Tfs*53 | Frame Shift Del (DEL) | VAF 16/97 reads (16%) | catalogued as rs570442888; called by mutect2, varscan2
- ADAM7 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs765178430, COSV51537362; called by muse, mutect2, varscan2
- ADAMTS10 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279202450, COSV54353125; called by muse, mutect2, varscan2
- ADAMTS13 | c.2284C>A p.L762M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as COSV63020746; called by muse, mutect2, varscan2
- ADAMTS9 | c.2564C>T p.S855L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as rs1227579877, COSV55777806; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs755580922, COSV57860263; called by muse, mutect2, varscan2
- ADAP2 | c.257A>C p.K86T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58295461; called by muse, mutect2, varscan2
- ADAR | c.3448C>T p.R1150W | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs999172070, COSV52713496; called by muse, mutect2, varscan2
- ADCY1 | c.2954T>A p.V985E | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52032336; called by muse, mutect2, varscan2
- ADCY10 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 25/105 reads (24%) | catalogued as rs531613788, COSV63239419; called by muse, mutect2, varscan2
- ADCY5 | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs1221027778, COSV59196136; called by muse, mutect2, varscan2
- ADCY7 | c.2960G>A p.R987H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757612325, COSV54265462; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 28/106 reads (26%) | catalogued as rs760140619; called by mutect2, varscan2
- ADRA1D | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745387589, COSV65240474; called by muse, mutect2, varscan2
- ADSS1 | c.574T>C p.F192L | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); catalogued as COSV58272784; called by muse, mutect2, varscan2
- AGAP1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1310810988, COSV58317983; called by muse, mutect2, varscan2
- AGBL5 | c.1266dup p.K423Qfs*28 | Frame Shift Ins (INS) | VAF 54/212 reads (25%) | catalogued as rs747733044; called by mutect2, varscan2
- AGBL5 | c.2437del p.R813Gfs*68 | Frame Shift Del (DEL) | VAF 29/123 reads (24%) | catalogued as rs759542168; called by mutect2, pindel, varscan2
- AGO3 | c.2377C>T p.R793C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179870833, COSV55792316; called by muse, mutect2, varscan2
- AGPAT1 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs975811201, COSV61247301; called by muse, mutect2, varscan2
- AGXT | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs767927978, COSV56753512; called by muse, mutect2, varscan2
- AHCY | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as rs199533546, COSV54152885; called by muse, mutect2, varscan2
- AHNAK | c.3809A>G p.E1270G | Missense Mutation (SNP) | VAF 98/389 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.712); catalogued as COSV57208636; called by muse, mutect2, varscan2
- AIRE | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.08); catalogued as rs758446796, COSV52393277; called by muse, mutect2, varscan2
- AK5 | c.290G>A p.R97Q (on ENST00000354567 / NM_174858.3; = p.R71Q on NM_012093.4) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.92); catalogued as rs377402236; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | catalogued as rs778351035; called by mutect2, pindel, varscan2
- AKAP12 | c.2846C>T p.T949M | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as rs766910226, COSV53572564; called by muse, mutect2, varscan2
- AKAP12 | c.3479dup p.D1161* | Frame Shift Ins (INS) | VAF 45/142 reads (32%) | catalogued as rs1211553290; called by mutect2, pindel, varscan2
- AKAP6 | c.4868G>A p.G1623D | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as COSV55209180; called by muse, varscan2
- AKAP6 | c.4913G>A p.R1638H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1043613753, COSV55209189; called by muse, varscan2
- AKAP8 | c.575A>G p.Q192R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.188); catalogued as rs1396458339, COSV54101832; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKT2 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.264); catalogued as rs1407888862, COSV100251357, COSV60908025; called by muse, mutect2, varscan2
- ALAS1 | c.1694G>T p.R565L | Missense Mutation (SNP) | VAF 97/442 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV59627313; called by muse, mutect2, varscan2
- ALDH1A3 | c.849del p.K284Rfs*83 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as rs758955164; called by mutect2, varscan2
- ALDH1B1 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs61757680; called by muse, mutect2, varscan2
- ALDH1B1 | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV66619504; called by muse, mutect2, varscan2
- ALDH2 | c.864dup p.K289Efs*45 | Frame Shift Ins (INS) | VAF 24/124 reads (19%) | catalogued as rs771889973; called by mutect2, varscan2
- ALDH5A1 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370988709; called by muse, mutect2
- ALG13 | c.3035A>G p.H1012R | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.102); catalogued as COSV52636894; called by muse, mutect2, varscan2
- ALMS1 | c.9796T>A p.L3266M | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52506562; called by muse, mutect2, varscan2
- ALPK1 | c.3063del p.K1021Nfs*18 | Frame Shift Del (DEL) | VAF 37/177 reads (21%) | catalogued as rs1159828137; called by mutect2, pindel, varscan2
- ALS2 | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs149670991, COSV51885571; called by muse, mutect2, varscan2
- AMDHD2 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53550178; called by muse, mutect2, varscan2
- AMIGO3 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.556); catalogued as COSV57537758; called by muse, mutect2, varscan2
- AMIGO3 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284860513, COSV57538050; called by muse, mutect2, varscan2
- AMMECR1L | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55760266; called by muse, mutect2, varscan2
- AMPD3 | c.299dup p.A101Gfs*29 (on ENST00000396553 / NM_001025389.2; = p.A110Gfs*29 on NM_000480.3) | Frame Shift Ins (INS) | VAF 48/214 reads (22%) | catalogued as rs751130603; called by mutect2, pindel, varscan2
- AMZ1 | c.1020G>A p.W340* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV56685798; called by muse, mutect2, varscan2
- ANAPC15 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 47/139 reads (34%) | catalogued as rs1265144473, COSV56191467, COSV99921493; called by muse, mutect2, varscan2
- ANAPC7 | c.1720G>T p.G574W | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV71443776; called by muse, mutect2, varscan2
- ANGPTL5 | c.813dup p.K272* | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | catalogued as rs765321536; called by mutect2, pindel, varscan2
- ANK2 | c.11681C>T p.T3894I | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.133); catalogued as rs1318639708, COSV52153228; called by muse, mutect2, varscan2
- ANKH | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52478916; called by muse, mutect2, varscan2
- ANKRD11 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56358161, COSV56362243; called by muse, mutect2, varscan2
- ANKRD13A | c.265A>G p.M89V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV55675721; called by muse, mutect2, varscan2
- ANKRD17 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.588); catalogued as rs762684239, COSV100428298, COSV58217949; called by muse, mutect2, varscan2
- ANKRD24 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV53669003; called by muse, mutect2, varscan2
- ANKRD34A | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60160567; called by muse, mutect2, varscan2
- ANKRD53 | c.823T>G p.F275V | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV55536799; called by muse, mutect2, varscan2
- ANKS1B | c.2657C>T p.P886L (on ENST00000547776 / NM_152788.4; = p.P112L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60359910; called by muse, mutect2, varscan2
- ANKS6 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs764702464, COSV62049749; called by muse, mutect2, varscan2
- ANO2 | c.1362C>G p.N454K (on ENST00000356134 / NM_001278597.3; = p.N458K on NM_001278596.3) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV59014443; called by muse, mutect2, varscan2
- AP2M1 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | catalogued as COSV53047556; called by muse, mutect2, varscan2
- APAF1 | c.1805del p.N602Tfs*8 (on ENST00000551964 / NM_181861.2; = p.N591Tfs*8 on NM_001160.3) | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | catalogued as rs758129366; called by mutect2, varscan2
- APC2 | c.1952A>C p.N651T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52017088; called by muse, mutect2
- APOBEC3F | c.460T>C p.Y154H | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV57910152; called by muse, varscan2
- APOC2 | c.25_26del p.L9Vfs*10 | Frame Shift Del (DEL) | VAF 23/126 reads (18%) | catalogued as rs755352904; called by pindel, varscan2
- APOL4 | c.812T>C p.V271A (on ENST00000352371 / NM_145660.2; = p.V268A on NM_030643.4) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs1204273340, COSV60654279; called by muse, mutect2, varscan2
- APTX | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 39/90 reads (43%) | catalogued as rs746541090, CM112331, COSV58928185; called by muse, mutect2, varscan2
- ARHGAP33 | c.2024T>G p.L675R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV50120521; called by muse, mutect2, varscan2
- ARHGAP35 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs199897795, COSV68329280; called by muse, mutect2, varscan2
- ARHGAP45 | c.2761C>T p.Q921* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV53123682; called by muse, mutect2, varscan2
- ARHGAP5 | c.576dup p.P193Tfs*8 | Frame Shift Ins (INS) | VAF 22/78 reads (28%) | catalogued as rs1269856893; called by mutect2, varscan2
- ARHGAP6 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.561); catalogued as rs750456871, COSV61625832; called by muse, mutect2, varscan2
- ARHGEF10L | c.2362C>A p.P788T | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV51430071; called by muse, mutect2, varscan2
- ARHGEF11 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs780005478, COSV59353176; called by muse, mutect2, varscan2
- ARHGEF18 | c.1384C>A p.L462M (on ENST00000359920 / NM_001130955.2; = p.L358M on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 153/638 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV60468371; called by muse, mutect2, varscan2
- ARHGEF18 | c.3356_3358del p.F1119del (on ENST00000359920 / NM_001130955.2; = p.F1015del on NM_015318.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs1351546343; called by pindel, varscan2
- ARHGEF2 | c.1771C>T p.R591W (on ENST00000361247 / NM_001162383.2; = p.R563W on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58108323; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 24/122 reads (20%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57600152; called by muse, mutect2, varscan2
- ARMC6 | c.310A>T p.S104C (on ENST00000392336; = p.S79C on NM_033415.4) | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54181014; called by muse, mutect2, varscan2
- ARRDC2 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV55843875; called by muse, mutect2, varscan2
- ARSL | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66965033; called by muse, mutect2, varscan2
- ARVCF | c.2171A>C p.K724T | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52889472; called by muse, mutect2, varscan2
- ASCC3 | c.5498A>T p.K1833M | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as COSV64973707; called by muse, mutect2, varscan2
- ASPG | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV71933699; called by muse, mutect2, varscan2
- ASRGL1 | c.894T>A p.D298E | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57124069; called by muse, mutect2, varscan2
- ASTN1 | c.967C>A p.H323N | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.275); catalogued as COSV56065281; called by muse, mutect2
- ASXL3 | c.5424G>T p.K1808N | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as COSV52461914, COSV52469489; called by muse, mutect2, varscan2
- ATAD2 | c.941A>G p.H314R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV54879166; called by muse, mutect2, varscan2
- ATG16L2 | c.1789G>A p.V597M | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1444911780, COSV58361422; called by muse, mutect2, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs771531141; called by mutect2, varscan2
- ATG4B | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.229); catalogued as rs973950184, COSV59871170; called by muse, mutect2, varscan2
- ATG9A | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as COSV54694472; called by muse, mutect2, varscan2
- ATG9B | c.2162del p.P721Qfs*62 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as COSV52486004; called by mutect2, pindel, varscan2
- ATMIN | c.2253A>G p.I751M | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV55145556; called by muse, mutect2
- ATP11B | c.1580C>A p.S527Y | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60027347; called by muse, mutect2, varscan2
- ATP11B | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60027356; called by muse, mutect2, varscan2
- ATP2B2 | c.2551G>A p.V851I (on ENST00000352432; = p.V817I on NM_001683.5) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs778120026, COSV59492636; called by muse, mutect2, varscan2
- ATP5F1A | c.919G>C p.A307P | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV56360007; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770611939, COSV57748369; called by muse, mutect2, varscan2
- ATP7A | c.4414C>T p.R1472C | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs782062633, COSV58444290; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ATP9B | c.2761G>A p.G921R | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553937934, COSV56948647; called by muse, mutect2, varscan2
- ATR | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs746970647, COSV63383507; called by muse, mutect2, varscan2
- ATRAID | c.754T>C p.S252P (on ENST00000611786; = p.S139P on NM_016085.5) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV53025069; called by muse, mutect2, varscan2
- ATXN7L3 | c.703C>T p.R235* (on ENST00000389384 / NM_001382309.1; = p.R242* on NM_001382308.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV60228497; called by muse, mutect2, varscan2
- AURKB | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs761178783, COSV60244062; called by muse, mutect2, varscan2
- AXL | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs374067962; called by muse, mutect2, varscan2
- BAG3 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV64841829; called by muse, mutect2, varscan2
- BAIAP2L1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV50055061; called by muse, mutect2, varscan2
- BARD1 | c.2230A>G p.N744D | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as rs1553612078, COSV53610458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAR1 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as rs769456547, COSV50779821; called by muse, mutect2, varscan2
- BCL11A | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV59626995; called by muse, mutect2, varscan2
- BCL6 | c.2047G>A p.A683T | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1230004461, COSV51650879; called by muse, mutect2, varscan2
- BCL6B | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs765843482, COSV53427087; called by muse, mutect2, varscan2
- BCL9L | c.3380del p.P1127Hfs*21 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs751794665; called by mutect2, varscan2
- BCOR | c.4741G>T p.D1581Y (on ENST00000378444 / NM_001123385.2; = p.D1547Y on NM_017745.6) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV60703908, COSV60706546, COSV60707363; called by muse, mutect2, varscan2
- BDH1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs749172620, COSV64018118; called by muse, mutect2, varscan2
- BDP1 | c.1101del p.F367Lfs*25 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | catalogued as rs1443704192; called by mutect2, pindel, varscan2
- BECN1 | c.358G>T p.G120W | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV64120659; called by muse, mutect2, varscan2
- BEND5 | c.1052del p.K351Rfs*15 | Frame Shift Del (DEL) | VAF 34/150 reads (23%) | catalogued as rs756345162, COSV65718189; called by mutect2, varscan2
- BEST3 | c.1332dup p.R445Qfs*58 | Frame Shift Ins (INS) | VAF 25/93 reads (27%) | catalogued as rs779566914; called by mutect2, varscan2
- BLNK | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782570122, COSV56409850; called by muse, mutect2
- BMPR1A | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.314); catalogued as COSV64405440; called by muse, mutect2, varscan2
- BNC1 | c.225del p.M76Cfs*14 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs751941533; called by mutect2, pindel, varscan2
- BRAF | c.1328del p.P443Lfs*8 (on ENST00000288602 / NM_001374244.1; = p.P403Lfs*8 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | catalogued as COSV56263190; called by mutect2, varscan2
- BRD8 | c.2252C>A p.P751H (on ENST00000254900 / NM_139199.2; = p.P824H on NM_006696.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50146162; called by muse, mutect2, varscan2
- BRINP2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.355); catalogued as rs751983601, COSV64176567; called by muse, mutect2, varscan2
- BRINP2 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1266621387, COSV64176570; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BRWD3 | c.2351G>A p.R784H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs760562830, COSV100956316, COSV64745902; called by muse, mutect2, varscan2
- BSPRY | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs369616461, COSV65242448; called by muse, mutect2, varscan2
- BTBD16 | c.1379G>A p.G460D | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV53261828; called by muse, mutect2, varscan2
- BTBD2 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs747021203, COSV55308114; called by muse, mutect2, varscan2
- BUD13 | c.1808G>A p.S603N | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.105); catalogued as COSV52767701; called by muse, mutect2, varscan2
- C10orf90 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1386226244, COSV52951341; called by muse, mutect2, varscan2
- C11orf54 | c.810del p.F270Lfs*18 (on ENST00000331239; = p.F220Lfs*18 on NM_014039.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/154 reads (16%) | catalogued as rs1243082072; called by mutect2, pindel, varscan2
- C16orf71 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.7); catalogued as rs376548562; called by muse, mutect2, varscan2
- C16orf91 | c.321G>T p.Q107H | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.371); catalogued as COSV59949857; called by muse, mutect2, varscan2
- C17orf80 | c.1366_1367del p.L456Sfs*114 | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | catalogued as rs1319876713; called by pindel, varscan2
- C19orf44 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99550577; called by muse, mutect2, varscan2
- C19orf57 | c.853A>T p.T285S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV60967376, COSV60967611; called by muse, mutect2, varscan2
- C21orf58 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.134); catalogued as rs1321986753, COSV52449165; called by muse, mutect2, varscan2
- C3 | c.2371A>G p.M791V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.97); PolyPhen benign (0.027); catalogued as rs1460034672, COSV55570881; called by muse, mutect2, varscan2
- C5AR1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs201947994, COSV61892337; called by muse, mutect2, varscan2
- C5AR1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs200066829, COSV61892216; called by muse, mutect2, varscan2
- C5AR1 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as rs200226809, COSV61892252; called by muse, mutect2, varscan2
- C5orf51 | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.366); catalogued as rs1561155575, COSV67565632; called by muse, mutect2, varscan2
- C7orf25 | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs1251786298, COSV63273395; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | catalogued as rs750339990; called by mutect2, pindel
- CA3 | c.308A>G p.H103R | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.511); catalogued as COSV53409521; called by muse, mutect2, varscan2
- CABIN1 | c.3538C>T p.R1180C | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs370402538; called by muse, mutect2, varscan2
- CABLES2 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV54156226; called by muse, mutect2, varscan2
- CABP5 | c.433del p.R145Gfs*24 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs769959570, COSV99506527; called by mutect2, pindel, varscan2
- CACNA1A | c.3720C>A p.C1240* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV64193888; called by muse, mutect2, varscan2
- CACNA1D | c.4349T>G p.L1450R (on ENST00000350061 / NM_001128840.3; = p.L1470R on NM_000720.4) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55442131; called by muse, mutect2, varscan2
- CACNA1I | c.5832A>G p.A1944= | Splice Region (SNP) | VAF 7/26 reads (27%) | catalogued as COSV60804160, COSV60818811; called by muse, mutect2, varscan2
- CACNA2D3 | c.663T>A p.F221L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV55512063, COSV55526249; called by muse, mutect2
- CAMK2D | c.1206T>G p.A402= | Splice Region (SNP) | VAF 34/117 reads (29%) | catalogued as COSV56428221; called by muse, mutect2, varscan2
- CAPN10 | c.1016C>T p.T339M | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs748401959, COSV54375519; called by muse, mutect2, varscan2
- CAPN10 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs1460275142, COSV54375544; called by muse, mutect2, varscan2
- CAPN12 | c.639G>T p.E213D | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV61015384; called by muse, mutect2, varscan2
- CARD9 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769183409, COSV53731970; called by muse, mutect2, varscan2
- CARMIL2 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs548311381, COSV58024589; called by muse, mutect2, varscan2
- CARMIL3 | c.247A>G p.I83V | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV57725619; called by muse, mutect2, varscan2
- CASQ2 | c.1134T>A p.D378E | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs150486780, COSV54769421; ClinVar: likely benign; called by muse, mutect2, varscan2
- CASS4 | c.2204G>A p.R735H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV64385785; called by muse, mutect2, varscan2
- CATSPERG | c.2442G>T p.E814D | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as COSV53047468; called by muse, mutect2, varscan2
- CBWD1 | c.1098G>T p.K366N | Missense Mutation (SNP) | VAF 43/343 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV100071361; called by muse, mutect2, varscan2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 48/166 reads (29%) | catalogued as rs780649799; called by mutect2, varscan2
- CCDC102A | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs752427469, COSV50776022; called by muse, mutect2, varscan2
- CCDC105 | c.623G>T p.S208I | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.351); catalogued as COSV52963221, COSV52965823; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC174 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778802009, COSV57980474; called by muse, mutect2, varscan2
- CCDC178 | c.2079-1G>T p.X693_splice (on ENST00000383096 / NM_001105528.3; = p.X655_splice on NM_198995.3) | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as COSV55760184; called by muse, mutect2, varscan2
- CCDC24 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV58843129; called by muse, mutect2, varscan2
- CCDC65 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs143876144; called by muse, mutect2, varscan2
- CCDC66 | c.1327C>T p.R443C (on ENST00000394672 / NM_001353147.1; = p.R409C on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371375228; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC89 | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as rs1206768012, COSV57033749; called by muse, mutect2, varscan2
- CCL24 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as rs1010478183, COSV56116014; called by muse, mutect2, varscan2
- CCN1 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs774059615, COSV71704306; called by muse, mutect2, varscan2
- CCNB3 | c.3301C>A p.P1101T | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV52071595; called by muse, mutect2, varscan2
- CCNJL | c.1201A>G p.M401V | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV57444059; called by muse, mutect2, varscan2
- CCR1 | c.200del p.N67Tfs*2 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | catalogued as rs943670629; called by mutect2, pindel, varscan2
- CD33 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as COSV51800784; called by muse, mutect2, varscan2
- CDAN1 | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62331420; called by muse, mutect2, varscan2
- CDC34 | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1227684760, COSV52742017; called by muse, mutect2
- CDC42BPB | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760767641, COSV63474415; called by muse, mutect2, varscan2
- CDC42BPG | c.1973A>C p.Q658P | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV61346386; called by muse, mutect2, varscan2
- CDC42EP4 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs770925940, COSV59962416; called by muse, mutect2, varscan2
- CDH18 | c.774A>T p.L258F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56911544; called by muse, mutect2, varscan2
- CDH23 | c.2690C>T p.A897V | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.186); catalogued as COSV54928715; called by muse, mutect2, varscan2
- CDH4 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs748187890, COSV64647842; called by muse, varscan2
- CDK11B | c.227G>T p.R76I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100478391; called by muse, mutect2, varscan2
- CDKL3 | c.1777T>C p.*593Qext*23 | Nonstop Mutation (SNP) | VAF 29/125 reads (23%) | catalogued as COSV54740579; called by muse, mutect2, varscan2
- CDKL5 | c.2653G>A p.G885R | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as rs398123694, COSV66110663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEBPE | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236429877, COSV52829414, COSV52829550; called by muse, mutect2, varscan2
- CECR2 | c.2792G>A p.R931H (on ENST00000342247 / NM_001290047.2; = p.R748H on NM_001290046.1) | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs371679902, COSV52838633; called by muse, mutect2, varscan2
- CELF3 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 55/137 reads (40%) | catalogued as COSV51882331; called by muse, mutect2, varscan2
- CELSR3 | c.3187A>G p.N1063D | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV50844319; called by muse, mutect2, varscan2
- CELSR3 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377325964, COSV50844345; called by muse, mutect2, varscan2
- CELSR3 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV50844375, COSV50858214; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CEP126 | c.2945G>A p.S982N | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs776815069, COSV54823454; called by muse, mutect2, varscan2
- CEP164 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1408605533, COSV54039718; called by muse, mutect2, varscan2
- CEP164 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV54038450; called by muse, mutect2, varscan2
- CEP250 | c.6094C>T p.R2032* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as rs773637285, COSV61169009; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 29/120 reads (24%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEP350 | c.3260G>A p.G1087E | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV62600320; called by muse, mutect2
- CES5A | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs745329592, COSV51865177; called by muse, mutect2, varscan2
- CFAP54 | c.4894T>C p.Y1632H | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV61571424; called by muse, mutect2, varscan2
- CFAP65 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV55391473; called by muse, mutect2
- CGN | c.3578T>G p.L1193R | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54968967; called by muse, mutect2, varscan2
- CGNL1 | c.3151G>A p.A1051T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs1249272831, COSV55565390; called by muse, mutect2, varscan2
- CHAMP1 | c.553_555del p.P185del | In Frame Del (DEL) | VAF 50/225 reads (22%) | catalogued as rs782253043; called by mutect2, pindel, varscan2
- CHAT | c.433A>G p.T145A | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.19); catalogued as COSV100341083; called by muse, mutect2, varscan2
- CHD3 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV57873659; called by muse, mutect2, varscan2
- CHD5 | c.1892T>C p.I631T | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV52410525; called by muse, mutect2, varscan2
- CHD7 | c.3866C>T p.A1289V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as CM133767, COSV71108412; called by muse, mutect2, varscan2
- CHD7 | c.4130C>T p.A1377V | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71108418; called by muse, mutect2, varscan2
- CHD7 | c.8090A>G p.E2697G | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV71108425; called by muse, mutect2, varscan2
- CHD8 | c.6115C>T p.Q2039* (on ENST00000646647 / NM_001170629.2; = p.Q1760* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as rs1555313275, COSV63036607; called by muse, mutect2, varscan2
- CHD8 | c.4405C>T p.R1469C (on ENST00000646647 / NM_001170629.2; = p.R1190C on NM_020920.4) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs375862520, COSV63219622; called by muse, mutect2, varscan2
- CHID1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60258363; called by muse, mutect2, varscan2
- CHPF2 | c.1941dup p.S648Lfs*6 | Frame Shift Ins (INS) | VAF 14/54 reads (26%) | catalogued as rs746469175; called by mutect2, varscan2
- CHRM2 | c.66A>T p.E22D | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV57768755; called by muse, mutect2, varscan2
- CHRM3 | c.589T>C p.F197L | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.045); catalogued as COSV55085197; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA4 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs752686095, COSV64718910; called by muse, mutect2, varscan2
- CHST15 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs368746217, COSV60566097; called by muse, mutect2, varscan2
- CHST4 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763003100, COSV58296722; called by muse, mutect2, varscan2
- CHST7 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1244338654, COSV52099565; called by muse, mutect2, varscan2
- CHST7 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as rs370937477, COSV52099574; called by muse, mutect2, varscan2
- CHSY1 | c.666dup p.P223Afs*29 | Frame Shift Ins (INS) | VAF 10/53 reads (19%) | catalogued as rs762321510; called by mutect2, varscan2
- CHTF18 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs370867046, COSV50100041; called by muse, mutect2, varscan2
- CIBAR1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1034801496, COSV63897055; called by muse, mutect2, varscan2
- CIT | c.1625T>C p.I542T | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); catalogued as COSV55864441; called by muse, mutect2, varscan2
- CKAP2 | c.1496G>A p.R499Q (on ENST00000378037 / NM_001098525.2; = p.R498Q on NM_018204.5) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs750005059, COSV51621445; called by muse, mutect2, varscan2
- CLCN2 | c.1429A>G p.M477V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs770219958, COSV55600274; called by muse, mutect2, varscan2
- CLDN18 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | catalogued as rs761116930, COSV51736198, COSV51737856; called by muse, mutect2, varscan2
- CLEC18B | c.992G>A p.G331D | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV60577089; called by muse, mutect2, varscan2
- CLEC2B | c.168G>A p.W56* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as rs559310189, COSV57308970; called by muse, mutect2, varscan2
- CLK2 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs1182369122, COSV62876794; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | catalogued as rs369752219; called by mutect2, varscan2
- CLUH | c.1324dup p.D442Gfs*99 (on ENST00000435359; = p.D480Gfs*99 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 10/41 reads (24%) | catalogued as rs752224729; called by mutect2, varscan2
- CMIP | c.1355C>T p.T452M (on ENST00000537098 / NM_198390.2; = p.T358M on NM_030629.3) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as rs369769411; called by muse, mutect2, varscan2
- CNGB1 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.496); catalogued as COSV51899175, COSV99202490; called by muse, mutect2, varscan2
- CNNM4 | c.1403-1G>T p.X468_splice | Splice Site (SNP) | VAF 5/31 reads (16%) | catalogued as COSV65660480; called by muse, mutect2, varscan2
- CNOT6 | c.614A>G p.Q205R | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); catalogued as COSV56160667; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 30/121 reads (25%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- CNTN2 | c.2377C>T p.R793C | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV59349128; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP4 | c.3316A>G p.I1106V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770637612, COSV56672591; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs374805044; called by mutect2, varscan2
- COG8 | c.326C>A p.A109E | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54742081; called by muse, mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 41/116 reads (35%) | catalogued as rs748995811; called by mutect2, varscan2
- COL14A1 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as COSV52850634; called by muse, mutect2, varscan2
- COL1A2 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV51955505; called by muse, mutect2
- COL1A2 | c.2313del p.G772Vfs*14 | Frame Shift Del (DEL) | VAF 20/108 reads (19%) | catalogued as COSV51953474; called by pindel, varscan2
- COL22A1 | c.4543G>A p.G1515S | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs931304758, COSV57330275, COSV57356553; called by muse, mutect2, varscan2
- COL23A1 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66788648; called by muse, mutect2, varscan2
- COL26A1 | c.664C>T p.R222* (on ENST00000313669 / NM_001278563.3; = p.R220* on NM_133457.4) | Nonsense Mutation (SNP) | VAF 14/24 reads (58%) | catalogued as rs772332259, COSV58122505; called by muse, mutect2, varscan2
- COL4A2 | c.1888G>T p.G630C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64626622; called by muse, mutect2, varscan2
- COL4A3 | c.4678G>A p.V1560I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as rs574102153, COSV67414364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.3136C>A p.L1046I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV65667389; called by muse, mutect2, varscan2
- COL5A3 | c.1413G>C p.Q471H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53408385; called by muse, mutect2, varscan2
- COL6A3 | c.837C>G p.I279M | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV55084605; called by muse, mutect2, varscan2
- COLEC10 | c.336del p.G113Afs*30 | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | catalogued as rs1286976627; called by mutect2, pindel, varscan2
- COMMD10 | c.607T>C p.*203Rext*19 | Nonstop Mutation (SNP) | VAF 32/104 reads (31%) | catalogued as COSV57235277; called by muse, varscan2
- CORIN | c.637A>G p.R213G | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs976677996, COSV56689050; called by muse, mutect2, varscan2
- CORO1A | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54630807; called by muse, mutect2, varscan2
- COX15 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 3/25 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV50012019; called by muse, mutect2
- COX7A1 | c.105_107del p.E35del | In Frame Del (DEL) | VAF 28/129 reads (22%) | catalogued as rs1441137634; called by pindel, varscan2
- COX8C | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as COSV56380880; called by muse, mutect2, varscan2
- CPLX3 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1049344660, COSV59001483; called by muse, mutect2, varscan2
- CPNE1 | c.1481G>A p.R494Q (on ENST00000352393; = p.R499Q on NM_003915.5) | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs754189553, COSV58290542; called by muse, mutect2, varscan2
- CPNE1 | c.959T>C p.L320P (on ENST00000352393; = p.L325P on NM_003915.5) | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58290550; called by muse, mutect2, varscan2
- CPT1C | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs753328360, COSV54918372; called by muse, mutect2, varscan2
- CPTP | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375729538, COSV59562612; called by muse, mutect2, varscan2
- CPXM2 | c.1312G>T p.G438* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | catalogued as COSV53859105; called by muse, mutect2, varscan2
- CRAT | c.495dup p.K166Efs*48 | Frame Shift Ins (INS) | VAF 68/314 reads (22%) | catalogued as rs772054700; called by mutect2, varscan2
- CREB3 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV59205948; called by muse, mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 33/161 reads (20%) | catalogued as rs762650691; called by mutect2, pindel, varscan2
- CSMD1 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.955); catalogued as COSV68185637; called by muse, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSNK1G3 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62054032; called by muse, mutect2, varscan2
- CTNNA3 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65566199; called by muse, mutect2, varscan2
- CTSW | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV57172048; called by muse, mutect2, varscan2
- CUL3 | c.1358del p.N453Tfs*2 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs1366667901; called by mutect2, pindel, varscan2
- CUL5 | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as rs1484567561, COSV67608517; called by muse, mutect2, varscan2
- CUL7 | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs749279996, COSV54814691; called by muse, mutect2, varscan2
- CYBRD1 | c.190A>G p.I64V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.334); catalogued as COSV58426264; called by muse, mutect2
- CYFIP2 | c.3227C>T p.A1076V (on ENST00000616178 / NM_001291722.2; = p.A1051V on NM_014376.4) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.178); catalogued as COSV59033106; called by muse, mutect2, varscan2
- CYP11A1 | c.322G>C p.A108P | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV51431301; called by muse, mutect2, varscan2
- CYP26A1 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV56417644; called by muse, mutect2, varscan2
- CYP26C1 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.163); catalogued as rs1426984843, COSV53321864; called by muse, mutect2
- CYP26C1 | c.656A>T p.E219V | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV53321872; called by muse, mutect2, varscan2
- CYP3A4 | c.140del p.L47Wfs*43 | Frame Shift Del (DEL) | VAF 36/94 reads (38%) | catalogued as rs1036437989; called by mutect2, pindel, varscan2
- DAAM2 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762052729, COSV51301902; called by muse, mutect2, varscan2
- DAPK1 | c.1345C>A p.L449I | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV63786221; called by muse, mutect2, varscan2
- DBNL | c.968C>T p.P323L (on ENST00000448521 / NM_001014436.3; = p.P324L on NM_014063.7) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1315272659, COSV51977472; called by muse, mutect2, varscan2
- DCHS1 | c.6067G>T p.A2023S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV55029759; called by muse, mutect2, varscan2
- DCHS1 | c.4211C>T p.A1404V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV55033067; called by muse, mutect2
- DCLK3 | c.1817A>G p.Q606R | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV69362801; called by muse, mutect2, varscan2
- DCP2 | c.405A>C p.E135D | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66616650; called by muse, mutect2, varscan2
- DDX10 | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV59433008; called by muse, mutect2, varscan2
- DDX50 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.614); catalogued as rs779954895, COSV65291769; called by muse, mutect2, varscan2
- DDX54 | c.2171C>T p.T724M | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.735); catalogued as rs373264271, COSV100013700; called by muse, mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 4/9 reads (44%) | catalogued as rs772416332; called by mutect2, varscan2
- DEAF1 | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs368901164, COSV58606441; called by muse, mutect2, varscan2
- DENND4B | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as rs1009990662, COSV63408010; called by muse, mutect2, varscan2
- DEPDC5 | c.3655C>T p.R1219W (on ENST00000400246; = p.R1288W on NM_014662.5) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1178940569, COSV56692595; called by muse, mutect2, varscan2
- DGAT2 | c.376T>C p.W126R | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57175790; called by muse, mutect2, varscan2
- DGCR6L | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as rs1222232797, COSV99956840, COSV99956933; called by muse, mutect2
- DGCR8 | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61226112; called by muse, mutect2, varscan2
- DGKD | c.2564del p.G855Vfs*48 (on ENST00000264057 / NM_152879.3; = p.G811Vfs*48 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 47/106 reads (44%) | catalogued as rs35538077; called by mutect2, pindel, varscan2
- DGKI | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as rs909132494, COSV55943265; called by muse, mutect2, varscan2
- DGKZ | c.2020G>A p.A674T (on ENST00000454345 / NM_001105540.2; = p.A486T on NM_003646.4) | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV58986620; called by muse, mutect2, varscan2
- DGLUCY | c.1435G>A p.G479S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.796); catalogued as rs777862658, COSV56365314; called by muse, mutect2, varscan2
- DHCR24 | c.1218C>T p.H406= | Splice Region (SNP) | VAF 5/13 reads (38%) | catalogued as rs777879250, COSV64874435; called by muse, mutect2, varscan2
- DHX36 | c.2266C>T p.H756Y | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57671624; called by muse, mutect2
- DHX37 | c.3145G>A p.A1049T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs755379720, COSV58133152; called by muse, varscan2
- DIDO1 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1264359122, COSV56615891; called by muse, varscan2
- DIS3 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs541536936, COSV66706028; called by muse, mutect2, varscan2
- DIS3L2 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1004734586, COSV56051200; called by muse, mutect2, varscan2
- DIS3L2 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs759646382, COSV56051231; called by muse, mutect2, varscan2
- DISP1 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs747659889, COSV52656866; called by muse, mutect2, varscan2
- DLC1 | c.2914A>G p.N972D (on ENST00000276297 / NM_001348081.2; = p.N535D on NM_006094.5) | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.304); catalogued as COSV52296760; called by muse, mutect2, varscan2
- DLL3 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1312810459, COSV52693884; called by muse, mutect2
- DMBT1 | c.2525G>C p.S842T | Missense Mutation (SNP) | VAF 76/341 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.099); catalogued as COSV57539077; called by muse, mutect2, varscan2
- DMD | c.5845C>A p.Q1949K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.83); PolyPhen benign (0.098); catalogued as CD973060, COSV63744037; called by muse, mutect2, varscan2
- DMP1 | c.896G>A p.S299N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV56819222; called by muse, mutect2, varscan2
- DNAAF5 | c.1302G>T p.E434D | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as COSV52415605; called by muse, mutect2, varscan2
- DNAH1 | c.11848C>T p.H3950Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56232451; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 22/42 reads (52%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH17 | c.5132C>T p.A1711V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV101103800; called by muse, mutect2, varscan2
- DNAH2 | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs200066704; called by muse, mutect2, varscan2
- DNAH3 | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV54512468; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAJB4 | c.618del p.W208Gfs*43 | Frame Shift Del (DEL) | VAF 20/91 reads (22%) | catalogued as rs1335993703, COSV66132198; called by mutect2, pindel, varscan2
- DNAJC1 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.041); catalogued as rs536392895, COSV65410027; called by muse, mutect2, varscan2
- DNAJC17 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53066728; called by muse, mutect2, varscan2
- DNAJC18 | c.395T>C p.V132A | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57415481; called by muse, mutect2, varscan2
- DNER | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs143332732; called by muse, mutect2, varscan2
- DNM2 | c.2369G>T p.G790V (on ENST00000355667 / NM_001005360.3; = p.G786V on NM_004945.3) | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.997); catalogued as COSV53033412; called by muse, varscan2
- DOCK10 | c.1272del p.F424Lfs*2 | Frame Shift Del (DEL) | VAF 29/126 reads (23%) | catalogued as rs1559599687; called by mutect2, pindel, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.4622C>T p.A1541V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV70235000; called by muse, mutect2
- DOK3 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1375659637, COSV57251163; called by muse, mutect2, varscan2
- DOK6 | c.221A>G p.E74G | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV66928368; called by muse, mutect2, varscan2
- DOP1A | c.5202T>A p.C1734* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV52708401; called by muse, mutect2, varscan2
- DOP1B | c.2561C>T p.T854M | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs202229502, COSV67692728; called by muse, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 30/122 reads (25%) | catalogued as rs35482889; called by mutect2, varscan2
- DPP3 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs200473591, COSV64756336; called by muse, mutect2, varscan2
- DPY19L3 | c.1863G>T p.E621D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV60475490; called by muse, mutect2, varscan2
- DPYSL3 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as COSV58325388; called by muse, mutect2, varscan2
- DRD2 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV60756245; called by muse, mutect2, varscan2
- DSC2 | c.398C>A p.A133D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV51862568; called by muse, mutect2, varscan2
- DSCAML1 | c.3238C>T p.R1080W (on ENST00000321322; = p.R1020W on NM_020693.4) | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1034319646, COSV58386656; called by muse, mutect2, varscan2
- DSEL | c.1355del p.G452Dfs*7 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as COSV59491427; called by mutect2, pindel, varscan2
- DSG2 | c.2219T>C p.M740T | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV55198070; called by muse, mutect2, varscan2
- DSP | c.8321T>C p.L2774P | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60939019; called by muse, mutect2, varscan2
- DST | c.21898C>T p.R7300W (on ENST00000361203 / NM_001374722.1; = p.R4973W on NM_015548.5) | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776951210, COSV55005569; called by muse, mutect2, varscan2
- DUOX1 | c.3015-2A>G p.X1005_splice | Splice Site (SNP) | VAF 23/103 reads (22%) | catalogued as rs771158337, COSV58479009; called by muse, mutect2, varscan2
- DUS3L | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as rs1326104009, COSV57831550; called by muse, mutect2, varscan2
- DYM | c.1375C>A p.L459I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53982383; called by muse, mutect2, varscan2
- DYNC1H1 | c.5400G>C p.Q1800H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV64135464; called by muse, mutect2, varscan2
- DYNC1H1 | c.9379C>T p.P3127S | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV64135469; called by muse, mutect2, varscan2
- DYNC1H1 | c.11548A>G p.T3850A | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV64135474; called by muse, mutect2, varscan2
- DYNC1LI2 | c.208C>A p.L70I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV50754317; called by muse, mutect2, varscan2
- DYNC2I1 | c.3170C>A p.A1057D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV68104171; called by muse, mutect2, varscan2
- DYTN | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65970587; called by muse, mutect2
- EBI3 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs554227389, COSV55689526; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | catalogued as rs369293935; called by mutect2, varscan2
- ECE1 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs372050311; called by muse, mutect2, varscan2
- ECE1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as rs1395366082, COSV51663022; called by muse, mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EEF1AKMT4-ECE2 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.69); catalogued as rs771043563, COSV62567182; called by muse, mutect2, varscan2
- EFHC1 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143655397; called by muse, mutect2, varscan2
- EFHC1 | c.1854A>G p.L618= | Splice Region (SNP) | VAF 14/68 reads (21%) | catalogued as COSV64135878; called by muse, mutect2, varscan2
- EGFLAM | c.800A>G p.D267G | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.176); catalogued as COSV59297051; called by muse, mutect2, varscan2
- EGR3 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57833018; called by muse, mutect2, varscan2
- EHD1 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as rs1314796245, COSV57734121; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375883951; called by muse, mutect2, varscan2
- EIF4G1 | c.1949G>A p.R650Q (on ENST00000346169 / NM_198241.3; = p.R454Q on NM_004953.5) | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV59989959; called by muse, mutect2, varscan2
- EIF4G1 | c.2809C>T p.R937C (on ENST00000346169 / NM_198241.3; = p.R742C on NM_004953.5) | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59989967; called by muse, mutect2, varscan2
- ELF4 | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 56/100 reads (56%) | catalogued as COSV57451971; called by muse, mutect2, varscan2
- ELMO2 | c.1280-2A>G p.X427_splice | Splice Site (SNP) | VAF 12/72 reads (17%) | catalogued as COSV51682202; called by muse, mutect2, varscan2
- ELOA2 | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV55296340; called by muse, mutect2, varscan2
- ELOVL4 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.267); catalogued as COSV63953571; called by muse, mutect2, varscan2
- EMILIN3 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV60035621; called by muse, mutect2
- EML1 | c.2390G>A p.S797N | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs756953819, COSV51743051; called by muse, mutect2, varscan2
- EML2 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as rs35928591, COSV55598462; called by muse, mutect2, varscan2
- EMX1 | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.916); catalogued as COSV50689330, COSV50690077; called by muse, mutect2, varscan2
- EMX1 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV50689339; called by muse, mutect2, varscan2
- ENKD1 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs373980533; called by muse, mutect2, varscan2
- ENKUR | c.230del p.N77Tfs*14 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | catalogued as rs749430462; called by mutect2, pindel
- ENO3 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 85/415 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs149301373; called by muse, mutect2, varscan2
- ENTPD4 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs556405061, COSV62268617; called by muse, mutect2, varscan2
- ENTPD8 | c.1222T>C p.Y408H (on ENST00000371506 / NM_001033113.2; = p.Y371H on NM_198585.3) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58161105; called by muse, mutect2, varscan2
- EPB41L4B | c.386A>G p.Q129R | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.547); catalogued as COSV65796357; called by muse, mutect2, varscan2
- EPHA2 | c.2824G>A p.D942N | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as rs1184554556, COSV100626218, COSV64452174; called by muse, mutect2, varscan2
- EPHA6 | c.2687G>A p.R896Q (on ENST00000389672 / NM_001080448.3; = p.R288Q on NM_173655.4) | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67561777; called by muse, mutect2, varscan2
- EPS8L1 | c.1569G>T p.Q523H (on ENST00000201647 / NM_133180.3; = p.Q396H on NM_017729.3) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1397434213, COSV52381068; called by muse, mutect2, varscan2
- ERBIN | c.1789-1G>A p.X597_splice | Splice Site (SNP) | VAF 14/46 reads (30%) | catalogued as COSV52313591; called by muse, mutect2, varscan2
- ERCC3 | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366074068, COSV53425366; called by muse, mutect2, varscan2
- ERCC6L2 | c.976G>T p.G326W | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV56629460; called by muse, mutect2, varscan2
- ERN1 | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70501206; called by muse, mutect2, varscan2
- ESRP2 | c.985-2A>G p.X329_splice (on ENST00000565858 / NM_001365264.1; = p.X319_splice on NM_024939.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 28/105 reads (27%) | catalogued as COSV52172768; called by muse, mutect2, varscan2
- ETS1 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs917270554, COSV60092582; called by muse, mutect2, varscan2
- ETV6 | c.613del p.L205Wfs*4 | Frame Shift Del (DEL) | VAF 71/325 reads (22%) | catalogued as rs1232497641; called by mutect2, pindel, varscan2
- EXOC1 | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs775167521, COSV62119674; called by muse, mutect2, varscan2
- EXOC8 | c.1745C>T p.T582M | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764776171, COSV50477861; called by muse, mutect2, varscan2
- EYA3 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100870306; called by muse, mutect2, varscan2
- F3 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs1464608979, COSV61844801; called by muse, mutect2, varscan2
- FA2H | c.601T>C p.S201P | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV54725748; called by muse, mutect2, varscan2
- FADS6 | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV59601964; called by muse, mutect2, varscan2
- FAM219A | c.492dup p.K165Qfs*39 (on ENST00000445726; = p.K148Qfs*39 on NM_147202.2 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 14/67 reads (21%) | catalogued as rs760074479; called by mutect2, varscan2
- FAM222A | c.596T>C p.I199T | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62723092; called by muse, mutect2, varscan2
- FAM222B | c.719del p.P240Rfs*3 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as COSV100368550, COSV100368697; called by pindel, varscan2
- FAM47C | c.2225C>A p.P742H | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV63723841, COSV63725306; called by muse, mutect2, varscan2
- FAM53C | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 45/150 reads (30%) | catalogued as COSV53511149; called by muse, mutect2, varscan2
- FAM76B | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs780302494, COSV62556236; called by muse, mutect2, varscan2
- FAM83F | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.063); catalogued as rs567145342, COSV60999800; called by muse, mutect2, varscan2
- FARP1 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs766670787, COSV60333498; called by muse, mutect2, varscan2
- FAT3 | c.11488G>A p.G3830R | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs929417822, COSV53092593, COSV99971784; called by muse, mutect2, varscan2
- FBH1 | c.2582A>T p.D861V (on ENST00000362091 / NM_178150.3; = p.D912V on NM_032807.4) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV62982110; called by muse, mutect2, varscan2
- FBN1 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.4); catalogued as rs141551765, CM145705; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN1 | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.919); catalogued as COSV57312953; called by muse, mutect2
- FBXO30 | c.2210T>C p.L737P | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52790699; called by muse, mutect2, varscan2
- FBXO46 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.332); catalogued as rs1184393247, COSV58348166; called by muse, mutect2, varscan2
- FBXW8 | c.362C>T p.A121V (on ENST00000309909; = p.A159V on NM_012174.1) | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs887081027, COSV59297823; called by muse, mutect2, varscan2
- FCGR2A | c.581C>T p.T194M (on ENST00000271450 / NM_001136219.3; = p.T193M on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs765336574, COSV54837762, COSV54838908; called by muse, mutect2, varscan2
- FER | c.1543C>T p.R515* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as CM157666, COSV55287062; called by muse, mutect2, varscan2
- FER1L6 | c.2165G>A p.W722* | Nonsense Mutation (SNP) | VAF 81/173 reads (47%) | catalogued as COSV67549032; called by muse, mutect2, varscan2
- FGF2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52648902; called by muse, mutect2, varscan2
- FGG | c.1054T>G p.C352G | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM044624, COSV60194912; called by muse, mutect2, varscan2
- FGL2 | c.1238T>C p.V413A | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV50380751; called by muse, mutect2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 37/143 reads (26%) | catalogued as COSV58769165; called by mutect2, varscan2
- FLG2 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs145274102, COSV101166045; called by muse, mutect2, varscan2
- FLT1 | c.166del p.E56Kfs*12 | Frame Shift Del (DEL) | VAF 29/105 reads (28%) | catalogued as COSV56720636; called by mutect2, pindel, varscan2
- FLYWCH1 | c.1105G>A p.V369M (on ENST00000253928 / NM_001308068.2; = p.V368M on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as rs757899219, COSV54144466; called by muse, mutect2, varscan2
- FN1 | c.6985C>T p.R2329C (on ENST00000359671 / NM_001365524.2; = p.R2298C on NM_002026.4) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759273898, COSV60549281; called by muse, mutect2
- FN1 | c.2222T>A p.V741D | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100118533; called by muse, mutect2, varscan2
- FN3KRP | c.468+2T>C p.X156_splice | Splice Site (SNP) | VAF 31/94 reads (33%) | catalogued as COSV53929243; called by muse, mutect2, varscan2
- FOLH1 | c.1501del p.S501Vfs*12 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | catalogued as rs764290022, COSV57049642; called by mutect2, pindel, varscan2
- FOXA3 | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs752761784, COSV56215336; called by muse, mutect2, varscan2
- FOXF1 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0.013); catalogued as COSV52285512; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 28/113 reads (25%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FTCD | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs776285015, COSV52424334; called by muse, mutect2, varscan2
- FUT3 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779363554, COSV54605204; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 26/51 reads (51%) | catalogued as rs756304971; called by mutect2, varscan2
- FYCO1 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 95/322 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs781455175, COSV56114899; called by muse, mutect2, varscan2
- G3BP1 | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62365904; called by muse, mutect2, varscan2
- GABRQ | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1412971894, COSV64781395; called by muse, mutect2, varscan2
- GAK | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs979901033, COSV58503252; called by muse, mutect2, varscan2
- GALNT15 | c.1354T>G p.F452V | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV60216204; called by muse, mutect2, varscan2
- GALNT16 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 58/229 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV61885258; called by muse, mutect2, varscan2
- GALP | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as COSV100628078; called by muse, mutect2, varscan2
- GALR2 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.107); catalogued as rs759763601, COSV57162070; called by muse, mutect2, varscan2
- GATA4 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs199922907, CM086821, COSV58732908; called by muse, mutect2, varscan2
- GBF1 | c.3346G>A p.D1116N (on ENST00000369983 / NM_001377137.1; = p.D1115N on NM_004193.3) | Missense Mutation (SNP) | VAF 111/387 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.248); catalogued as COSV64143846; called by muse, mutect2, varscan2
- GBF1 | c.3595C>T p.R1199W (on ENST00000369983 / NM_001377137.1; = p.R1198W on NM_004193.3) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370972697; called by muse, mutect2, varscan2
- GFRA2 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV60778394; called by muse, mutect2
- GGN | c.1663A>G p.T555A | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.591); catalogued as COSV53056473; called by muse, mutect2, varscan2
- GIMAP8 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV56230588; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | catalogued as rs750227570; called by mutect2, varscan2
- GINS4 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV52531126; called by muse, varscan2
- GJC2 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100813033, COSV64513176; called by muse, mutect2, varscan2
- GKN2 | c.140del p.N47Ifs*38 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as COSV61032094; called by mutect2, pindel, varscan2
- GLCCI1 | c.1281G>T p.K427N | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56200863; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 61/241 reads (25%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLIPR1L2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.353); catalogued as rs550463995, COSV57553070, COSV57553633; called by muse, mutect2, varscan2
- GLIS1 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs201662227, COSV100389850, COSV56546409; called by muse, mutect2, varscan2
- GLRX2 | c.334C>A p.L112I (on ENST00000367439 / NM_197962.3; = p.L113I on NM_016066.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66471792; called by muse, mutect2, varscan2
- GMDS | c.964A>T p.K322* | Nonsense Mutation (SNP) | VAF 40/123 reads (33%) | catalogued as COSV66413566; called by muse, mutect2, varscan2
- GMEB2 | c.881T>C p.V294A | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV56606348; called by muse, mutect2, varscan2
- GMIP | c.2584C>T p.R862C | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs138311100; called by muse, mutect2, varscan2
- GNG13 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200381353, COSV50210270; called by muse, mutect2, varscan2
- GOLGA7B | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs778985189, COSV53999392; called by muse, mutect2, varscan2
- GP1BA | c.1480del p.T494Pfs*59 | Frame Shift Del (DEL) | VAF 32/129 reads (25%) | catalogued as rs759573909; called by mutect2, pindel, varscan2
- GPATCH2L | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.99); catalogued as COSV55047575; called by muse, mutect2, varscan2
- GPATCH8 | c.2602C>T p.R868C | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV59193873; called by muse, mutect2, varscan2
- GPATCH8 | c.482C>A p.A161E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59193880; called by muse, mutect2, varscan2
- GPC5 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV65587763; called by muse, mutect2, varscan2
- GPD1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.223); catalogued as rs565703593, COSV56547687, COSV56548417, COSV99993940; called by muse, mutect2, varscan2
- GPI | c.464T>G p.I155S | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV62893663; called by muse, mutect2, varscan2
- GPR182 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs771196981, COSV55625862; called by muse, mutect2, varscan2
- GPR27 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as COSV55203551; called by muse, mutect2, varscan2
- GPR37 | c.1391T>C p.V464A | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.401); catalogued as COSV58256156; called by muse, mutect2, varscan2
- GPR78 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs570019246, COSV66762750; called by muse, mutect2, varscan2
- GPRIN1 | c.59del p.P20Qfs*23 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as rs752522649; called by mutect2, pindel, varscan2
- GPS1 | c.871A>G p.I291V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57648260; called by muse, mutect2, varscan2
- GRIK2 | c.1748+2T>C p.X583_splice | Splice Site (SNP) | VAF 23/103 reads (22%) | catalogued as COSV59713798, COSV59724702; called by muse, mutect2, varscan2
- GRIN2D | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV54377836; called by muse, mutect2
- GRIP1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367921418, COSV54045974; called by muse, mutect2, varscan2
- GRM3 | c.2063A>G p.Q688R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64469324; called by muse, mutect2, varscan2
- GRM7 | c.2427del p.F809Lfs*21 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs747773579; called by mutect2, varscan2
- GRM8 | c.2267G>A p.S756N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.012); catalogued as COSV58815027; called by muse, mutect2, varscan2
- GSAP | c.1448T>C p.M483T | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV57529067; called by muse, mutect2, varscan2
- GSC2 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50082266; called by muse, mutect2, varscan2
- GSG1L | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1174353861, COSV66585933; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2411C>T p.A804V | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV63100231; called by muse, mutect2, varscan2
- GTF2IRD2 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1422871321; called by muse, mutect2
- GTF2IRD2B | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1554532927, COSV57032667; called by mutect2, varscan2
- GUF1 | c.989A>G p.E330G | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV55781975; called by muse, mutect2
- GYPC | c.343C>A p.L115I | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV52145679; called by muse, varscan2
- HACD1 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs782115025, COSV63516183; called by muse, varscan2
- HAGH | c.646-1G>T p.X216_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | catalogued as COSV68400395; called by muse, mutect2
- HARS1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408800953, COSV100298377, COSV56905954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDAC11 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.177); catalogued as COSV55472713; called by muse, mutect2, varscan2
- HDAC4 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs761550650, COSV61860027; called by muse, mutect2, varscan2
- HDAC5 | c.899T>C p.I300T | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as COSV56817923; called by muse, mutect2, varscan2
- HDAC6 | c.2962G>A p.A988T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV61928189; called by muse, mutect2, varscan2
- HDGFL2 | c.1637T>G p.L546R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56682130; called by muse, mutect2, varscan2
- HEATR1 | c.2006C>G p.A669G | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV63980255; called by muse, mutect2, varscan2
- HEATR1 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.71); catalogued as COSV63979369; called by muse, mutect2, varscan2
- HECTD4 | c.12004G>A p.A4002T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs746900553, COSV66389216; called by muse, mutect2, varscan2
- HECTD4 | c.10045A>G p.M3349V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV66389224; called by muse, mutect2, varscan2
- HECW1 | c.3847A>G p.T1283A | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV67826075; called by muse, mutect2, varscan2
- HELLS | c.1840del p.R614Efs*11 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs745837238; called by mutect2, varscan2
- HELZ | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs200790914, COSV62376967; called by muse, mutect2, varscan2
- HELZ2 | c.3119C>T p.A1040V (on ENST00000467148 / NM_001037335.2; = p.A471V on NM_033405.3) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs374824256; called by muse, mutect2, varscan2
- HERC5 | c.1854C>T p.D618= | Splice Region (SNP) | VAF 6/28 reads (21%) | catalogued as rs369956338; called by muse, mutect2
- HERC6 | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.025); catalogued as COSV52028905; called by muse, mutect2
- HGS | c.947C>A p.A316E | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.57); catalogued as COSV61267183; called by muse, mutect2, varscan2
- HHIPL2 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.849); catalogued as rs548883263, COSV58564183; called by muse, mutect2
- HIC1 | c.1366G>A p.V456M (on ENST00000322941 / NM_001098202.1; = p.V437M on NM_006497.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs765775523, COSV53965112; called by muse, mutect2, varscan2
- HIP1 | c.2309G>A p.R770K | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV61184560, COSV61190065; called by muse, mutect2, varscan2
- HIPK3 | c.2164A>G p.N722D | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV57561682; called by muse, mutect2, varscan2
- HIRA | c.176T>A p.I59N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV54273575; called by muse, mutect2, varscan2
- HIVEP3 | c.1660del p.H554Tfs*20 | Frame Shift Del (DEL) | VAF 21/79 reads (27%) | catalogued as rs1558087190; called by mutect2, pindel, varscan2
- HLA-B | c.681C>A p.C227* | Nonsense Mutation (SNP) | VAF 41/180 reads (23%) | catalogued as COSV69520836; called by muse, varscan2
- HMOX1 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs747303322, COSV53339402; called by muse, mutect2, varscan2
- HNRNPH2 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs782704910, COSV54508591; called by muse, mutect2, varscan2
- HOXA7 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 57/311 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs559344881, COSV54217061; called by muse, mutect2, varscan2
- HOXC4 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 61/295 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.441); catalogued as rs776852773, COSV57698552; called by muse, mutect2, varscan2
- HRG | c.1223G>A p.C408Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51644717; called by muse, mutect2, varscan2
- HS1BP3 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV58312424; called by muse, mutect2, varscan2
- HSF4 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs374589300, COSV50456837, COSV99263630; called by muse, mutect2, varscan2
- HSP90AB1 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.65); catalogued as rs199628089, COSV62335185; called by muse, mutect2, varscan2
- HSPG2 | c.9694C>T p.R3232C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs767115080, COSV65932938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPG2 | c.7006C>A p.P2336T | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.598); catalogued as rs745663099, COSV101021192, COSV65970257; called by muse, mutect2, varscan2
- HTR1A | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.456); catalogued as rs775709782, COSV100108945, COSV60500307; called by muse, mutect2, varscan2
- HTR1D | c.955G>A p.V319M | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs567276499, COSV58447721; called by muse, mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- HYAL1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587595632, COSV56497165; called by muse, mutect2, varscan2
- IBTK | c.1216del p.I406Ffs*22 | Frame Shift Del (DEL) | VAF 43/168 reads (26%) | catalogued as rs1244845350, COSV100090077; called by mutect2, pindel, varscan2
- ICAM4 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.353); catalogued as COSV53424218; called by muse, mutect2
- ICAM5 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV55746625; called by muse, mutect2
- IER5 | c.8T>A p.F3Y | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.251); catalogued as COSV62536998; called by muse, mutect2, varscan2
- IFNA7 | c.563A>G p.K188R | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV53330784; called by muse, mutect2, varscan2
- IGDCC3 | c.608A>G p.D203G | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60077084; called by muse, mutect2, varscan2
- IGF1R | c.493T>A p.S165T | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.025); catalogued as COSV51275366; called by muse, mutect2, varscan2
- IGF2R | c.4947G>A p.A1649= | Splice Region (SNP) | VAF 21/67 reads (31%) | catalogued as rs774685428, COSV63627799; called by muse, mutect2, varscan2
- IGHMBP2 | c.1539C>T p.G513= | Splice Region (SNP) | VAF 7/18 reads (39%) | catalogued as rs746624957, COSV54821394; called by muse, mutect2, varscan2
- IGHV3-23 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 39/617 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.483); catalogued as rs1555466946; called by muse, mutect2
- IGLV3-16 | c.147del p.K49Nfs*17 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | catalogued as rs746629447; called by mutect2, varscan2
- IGSF8 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as COSV58757715; called by muse, mutect2, varscan2
- IL15RA | c.94A>C p.T32P | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66092477; called by muse, mutect2, varscan2
- IL16 | c.2221A>G p.N741D (on ENST00000302987 / NM_172217.5; = p.N40D on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1417305080, COSV57261909; called by muse, mutect2, varscan2
- IL23R | c.1820C>A p.S607Y | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV61373694; called by muse, mutect2, varscan2
- IL26 | c.429+2T>C p.X143_splice | Splice Site (SNP) | VAF 3/21 reads (14%) | catalogued as COSV57488625; called by muse, mutect2
- ILK | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as rs377094824; called by muse, mutect2, varscan2
- IMPDH1 | c.605G>A p.R202H (on ENST00000470772 / NM_001142573.2; = p.R288H on NM_000883.4) | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1027214657, COSV58315304; called by muse, mutect2, varscan2
- IMPG1 | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.467); catalogued as rs752856075, COSV64054476; called by muse, mutect2, varscan2
- INPP5E | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs370661476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INSRR | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.243); catalogued as COSV63871878; called by muse, mutect2, varscan2
- INTS4 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs765120138, COSV101417186, COSV71087626; called by muse, mutect2, varscan2
- IQGAP3 | c.2656C>T p.R886* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as rs138977257, COSV63250393; called by muse, mutect2, varscan2
- IRF2BP1 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as rs777841092, COSV56193201; called by muse, mutect2, varscan2
- IRS4 | c.1262G>T p.R421M | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV64533155; called by muse, mutect2, varscan2
- IRS4 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1349498571, COSV64533158; called by muse, mutect2, varscan2
- ITGA11 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV59876315; called by muse, mutect2, varscan2
- ITGA3 | c.2219+1G>A p.X740_splice | Splice Site (SNP) | VAF 21/65 reads (32%) | catalogued as rs200623247, COSV50307604; called by muse, mutect2, varscan2
- ITGB1 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV56480344; called by muse, mutect2, varscan2
- ITGB5 | c.1696C>A p.H566N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.982); catalogued as COSV56147809; called by muse, mutect2, varscan2
- ITPR2 | c.3868G>A p.E1290K | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as rs1012224377, COSV67267037; called by muse, mutect2, varscan2
- ITPRID2 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1354136648, COSV57470462, COSV57472147; called by muse, mutect2, varscan2
- JAKMIP1 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51525986; called by muse, mutect2, varscan2
- JARID2 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs771552957, COSV59187378; called by muse, varscan2
- JPH2 | c.875T>C p.M292T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1380514288, COSV65902645; called by muse, mutect2, varscan2
- JPH4 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.676); catalogued as rs1471055950, COSV58111290; called by muse, mutect2
- JSRP1 | c.24G>A p.W8* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV55558566; called by muse, mutect2, varscan2
- KALRN | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53758524; called by muse, mutect2, varscan2
- KALRN | c.951G>T p.Q317H | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768503730, COSV53758537; called by muse, mutect2, varscan2
- KANK1 | c.3559T>C p.C1187R | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66527661; called by muse, varscan2
- KAT14 | c.598G>T p.G200* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV66607159; called by muse, mutect2, varscan2
- KAT6B | c.4878C>A p.Y1626* | Nonsense Mutation (SNP) | VAF 45/125 reads (36%) | catalogued as COSV54744684; called by muse, mutect2, varscan2
- KATNAL2 | c.1594C>T p.Q532* (on ENST00000356157 / NM_001353899.1; = p.Q460* on NM_031303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV55296349; called by muse, mutect2, varscan2
- KATNBL1 | c.433del p.S145Lfs*19 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | catalogued as rs1206265094; called by mutect2, pindel, varscan2
- KBTBD2 | c.1202G>T p.R401I | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV58362767; called by muse, mutect2, varscan2
- KCNA5 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs1275665670, COSV52903813; called by muse, mutect2, varscan2
- KCNG4 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369952898; called by muse, mutect2, varscan2
- KCNH5 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs745970423, COSV59752965, COSV59755413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNH8 | c.2352del p.N785Tfs*10 | Frame Shift Del (DEL) | VAF 21/92 reads (23%) | catalogued as rs760381227; called by mutect2, pindel, varscan2
- KCNK13 | c.1171del p.V391Wfs*7 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs766469179, COSV56415804; called by mutect2, pindel, varscan2
- KCNV1 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192812890; called by muse, mutect2, varscan2
- KCTD1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs201028403; called by muse, mutect2, varscan2
- KCTD3 | c.2416del p.S806Vfs*16 | Frame Shift Del (DEL) | VAF 20/109 reads (18%) | catalogued as rs754600318; called by mutect2, pindel, varscan2
- KDM3B | c.3950del p.P1317Rfs*10 | Frame Shift Del (DEL) | VAF 25/124 reads (20%) | catalogued as rs1561792565; called by mutect2, pindel, varscan2
- KDM4A | c.2312T>C p.L771P | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV64959156; called by muse, mutect2, varscan2
- KDM6A | c.3917T>C p.L1306S | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV65038622; called by muse, mutect2, varscan2
- KDM6B | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as rs145085233; called by mutect2, varscan2
- KIAA0100 | c.6476A>T p.D2159V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56381526; called by muse, mutect2, varscan2
- KIAA0232 | c.2353del p.T785Hfs*4 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs1560202607; called by mutect2, pindel, varscan2
- KIAA0232 | c.4009G>A p.V1337M | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56923473; called by muse, mutect2, varscan2
- KIAA1143 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56088802; called by muse, mutect2, varscan2
- KIAA2013 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs775450441, COSV64860417; called by muse, mutect2, varscan2
- KIF13A | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs377225601; called by muse, mutect2, varscan2
- KIF16B | c.2341C>T p.R781C | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.308); catalogued as rs142424331; called by muse, mutect2, varscan2
- KIF21A | c.2148del p.V717Lfs*12 (on ENST00000361418 / NM_001378440.1; = p.V704Lfs*12 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs1193021160; called by mutect2, pindel, varscan2
- KIF21B | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 155/358 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs748876558, COSV59754906; called by muse, mutect2, varscan2
- KIF23 | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs1190900473, COSV52978418; called by muse, mutect2, varscan2
- KIF26A | c.2819C>T p.A940V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs375537598; called by muse, mutect2, varscan2
- KIF3B | c.1968+2T>C p.X656_splice | Splice Site (SNP) | VAF 26/76 reads (34%) | catalogued as COSV65227179; called by muse, mutect2, varscan2
- KLC4 | c.1418T>C p.L473P | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52434462; called by muse, mutect2, varscan2
- KLF16 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1464155965, COSV51736425; called by muse, mutect2
- KLF3 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.625); catalogued as rs761153626, COSV54710152; called by muse, mutect2, varscan2
- KLHDC7A | c.1707G>A p.W569* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as rs1478834969, COSV68769349; called by muse, mutect2, varscan2
- KLHL1 | c.104del p.G35Efs*31 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | catalogued as rs749011008; called by mutect2, pindel, varscan2
- KLHL17 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs202077085, COSV58531272; called by muse, mutect2, varscan2
- KLHL18 | c.1085C>T p.T362I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1187644044, COSV51744725; called by muse, mutect2, varscan2
- KLHL26 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs148044384; called by muse, mutect2, varscan2
- KLK3 | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58099562; called by muse, mutect2
- KPNB1 | c.2270A>G p.Y757C | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51595875; called by muse, mutect2, varscan2
- KREMEN1 | c.860G>A p.R287H (on ENST00000407188; = p.R289H on NM_032045.5) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1231622663, COSV59912096; called by muse, mutect2, varscan2
- KRT20 | c.1091A>G p.E364G | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51424375; called by muse, mutect2, varscan2
- KRT28 | c.518A>G p.D173G | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60684595; called by muse, mutect2, varscan2
- KRT3 | c.718T>C p.S240P | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV58815097; called by muse, mutect2, varscan2
- KRT34 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs140889696, COSV67450274; called by muse, mutect2, varscan2
- L1CAM | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 68/116 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1557091788, COSV62827445, COSV62827906; called by muse, mutect2, varscan2
- L3MBTL3 | c.1987G>A p.V663I | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs748606569, COSV62385192, COSV62387937; called by muse, mutect2, varscan2
- LAMA5 | c.8174A>G p.Q2725R | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV53356430; called by muse, mutect2, varscan2
- LAMB2 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753645487, COSV59732119; called by muse, mutect2, varscan2
- LAMB2 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs759728774, COSV59732127; called by muse, mutect2, varscan2
- LAMB3 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.542); catalogued as COSV61916069; called by muse, mutect2, varscan2
- LAMC3 | c.2914G>A p.A972T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs781181695, COSV63089747; called by muse, mutect2, varscan2
- LANCL2 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV54648580; called by muse, mutect2, varscan2
- LARGE1 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV61659807; called by muse, mutect2, varscan2
- LARP1B | c.2361del p.K787Nfs*26 | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | catalogued as rs758463950; called by mutect2, varscan2
- LCLAT1 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV58371543; called by muse, mutect2, varscan2
- LCN2 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as COSV52979973; called by muse, mutect2, varscan2
- LCN6 | c.332C>G p.A111G | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57910057, COSV57910613; called by muse, mutect2, varscan2
- LDLRAD4 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs747717376, COSV63335507; called by muse, mutect2, varscan2
- LEF1 | c.821A>G p.H274R | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.244); catalogued as COSV54465565; called by muse, mutect2, varscan2
- LGI1 | c.1070C>T p.T357I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV65057754; called by muse, mutect2, varscan2
- LHFPL4 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs780699330, COSV55001501; called by muse, mutect2, varscan2
- LHFPL4 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.49); catalogued as COSV55001508; called by muse, mutect2, varscan2
- LIG3 | c.2869C>T p.R957C | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756649783, COSV52006721; called by muse, varscan2
- LIN7A | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747194295, COSV54017859; called by muse, mutect2, varscan2
- LIPE | c.2410G>T p.G804C | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54922064; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs780042765; called by mutect2, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 26/91 reads (29%) | catalogued as rs765287063; called by mutect2, varscan2
- LMX1A | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764888037, COSV54218729; called by muse, mutect2, varscan2
- LMX1B | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as rs777089988, COSV62738770; called by muse, mutect2, varscan2
- LNX2 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 90/304 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV60334937; called by muse, varscan2
- LPA | c.5303dup p.N1768Kfs*5 | Frame Shift Ins (INS) | VAF 24/85 reads (28%) | catalogued as rs754637067; called by mutect2, varscan2
- LRFN2 | c.1176dup p.K393Qfs*38 | Frame Shift Ins (INS) | VAF 15/70 reads (21%) | catalogued as rs775972328; called by mutect2, pindel, varscan2
- LRIG1 | c.1016G>A p.S339N | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.088); catalogued as COSV56238575; called by muse, mutect2, varscan2
- LRP1B | c.3848T>A p.L1283H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67201076; called by muse, mutect2, varscan2
- LRP2BP | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as rs140807270; called by muse, mutect2, varscan2
- LRP3 | c.2108G>A p.C703Y | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV53503116; called by muse, mutect2
- LRP5 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766589610, COSV53713441; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRPAP1 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs148077268; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC3 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs1425743029, COSV52398749; called by muse, mutect2, varscan2
- LRRC7 | c.3905G>T p.G1302V (on ENST00000651989 / NM_001370785.2; = p.G1269V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV50432517; called by muse, mutect2, varscan2
- LRRIQ3 | c.1134del p.P379Lfs*26 | Frame Shift Del (DEL) | VAF 25/106 reads (24%) | catalogued as rs751977298; called by mutect2, pindel, varscan2
- LRRK2 | c.4915del p.R1639Gfs*15 | Frame Shift Del (DEL) | VAF 22/95 reads (23%) | catalogued as rs756089224; called by mutect2, varscan2
- LSS | c.2180C>T p.A727V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV62700424; called by muse, mutect2, varscan2
- LTN1 | c.2738A>T p.D913V | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV63733381; called by muse, mutect2, varscan2
- LTN1 | c.1435dup p.T479Nfs*26 | Frame Shift Ins (INS) | VAF 37/160 reads (23%) | catalogued as rs1158845924; called by mutect2, pindel, varscan2
- LUZP1 | c.1958G>A p.G653D | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV56499926; called by muse, mutect2, varscan2
- LZTR1 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs764415634, COSV53146297; called by muse, mutect2, varscan2
- LZTR1 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1213535694, COSV53146312; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAB21L4 | c.1282C>T p.R428W (on ENST00000388934 / NM_001085437.3; = p.R260W on NM_024861.4) | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs769118806, COSV56743132; called by muse, mutect2, varscan2
- MACF1 | c.21424G>A p.G7142R (on ENST00000372915; = p.G5187R on NM_012090.5) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | catalogued as COSV57113923, COSV57124546; called by muse, varscan2
- MACROD2 | c.623G>T p.W208L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53964116; called by muse, mutect2, varscan2
- MACROH2A1 | c.998C>T p.A333V (on ENST00000510038; = p.A332V on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV56894152; called by muse, mutect2, varscan2
- MAFB | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV64826485; called by muse, mutect2, varscan2
- MAG | c.1397G>A p.S466N | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV62699860; called by muse, mutect2, varscan2
- MAGEC2 | c.809C>A p.P270H | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55997575; called by muse, mutect2, varscan2
- MAGI2 | c.2401C>T p.P801S | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.715); catalogued as rs1430461191, COSV62643246; called by muse, mutect2, varscan2
- MAK | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs371774117; called by muse, mutect2, varscan2
- MAMSTR | c.485del p.P162Hfs*14 (on ENST00000318083 / NM_001130915.2; = p.P59Hfs*14 on NM_182574.2) | Frame Shift Del (DEL) | VAF 29/124 reads (23%) | catalogued as rs752869239; called by mutect2, varscan2
- MAP3K13 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 76/339 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs765143232, COSV53985938; called by muse, mutect2, varscan2
- MAP3K4 | c.479del p.N160Mfs*8 | Frame Shift Del (DEL) | VAF 29/96 reads (30%) | catalogued as COSV62334603; called by mutect2, varscan2
- MAP4K4 | c.2318C>T p.T773M (on ENST00000347699 / NM_001242559.2; = p.T691M on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as rs545368433, COSV56328437; called by muse, mutect2, varscan2
- MAP7D1 | c.245dup p.Q83Afs*8 | Frame Shift Ins (INS) | VAF 23/98 reads (23%) | catalogued as rs765962881; called by mutect2, varscan2
- MARVELD2 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.451); catalogued as rs756888886, COSV57780093; called by muse, mutect2, varscan2
- MARVELD2 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.054); catalogued as COSV57780104; called by muse, mutect2, varscan2
- MAST4 | c.4175C>T p.P1392L (on ENST00000403625 / NM_001164664.2; = p.P1203L on NM_015183.3) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368529481, COSV99845224; called by muse, mutect2, varscan2
- MATR3 | c.1858_1859del p.S620Ffs*5 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs1561942649; called by pindel, varscan2
- MAX | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs769051095, COSV52416063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MBD3 | c.50G>T p.R17M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as COSV50083193; called by muse, mutect2, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as rs762648935; called by mutect2, varscan2
- MCF2L2 | c.1088A>G p.H363R | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV61051322; called by muse, mutect2
- MCM3AP | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as rs776926615, COSV52438112; called by muse, mutect2, varscan2
- MDN1 | c.16147T>C p.Y5383H | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101021919; called by muse, mutect2, varscan2
1,434 further variants in this file (916 protein-altering or splice-affecting, 482 silent, 36 other) are not listed here.
